Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IF, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IF-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) ANTERIOR APEX:
PROSTATIC ADENOCARCINOMA INVOLVING SKELETAL MUSCLE.
- (B) ANTERIOR APEX #2:
PROSTATIC ADENOCARCINOMA INVOLVING SKELETAL MUSCLE.
INKED MARGIN FREE OF TUMOR.
- (C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.
- (D) RIGHT PELVIC LYMPH NODES:
Twenty lymph nodes, no tumor present. (0/22)
- (E) LEFT PELVIC LYMPH NODES:
Eleven lymph nodes, no tumor present. (0/11)

CLUE *ICD0-3*
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 861.9
9/5 11/24/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) ANTERIOR APEX - Received is a 0.3 cm in greatest dimension fragment of tan-pink soft tissue that is oriented by the surgeon as follows: ink at margin. The specimen is submitted entirely in A, for frozen section diagnosis.
*FS/DX: ADENOCARCINOMA INVOLVING SKELETAL MUSCLE.
- (B) ANTERIOR APEX #2 - INKED AT MARGIN - The specimen consists of a small tan piece of tissue (0.3 x 0.2 x 0.2 cm) with previously inked margin. The margin is reinked black. The specimen is submitted in toto in one cassette labeled B for frozen section.
*FS/DX: PROSTATIC ADENOCARCINOMA, MARGIN FREE OF TUMOR.
- (C) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.
- (D) RIGHT PELVIC LYMPH NODES - A tan-yellow segment of fat (14.5 x 3.6 x 1.3 cm) with twenty-three possible lymph nodes identified ranging from 0.2 to 1.3 cm in greatest dimension. All nodal tissue is submitted.
SECTION CODE: D1-D3, five possible lymph nodes each; D4, four possible lymph nodes; D5, three possible lymph nodes; D6, one possible lymph node, bisected.
- (E) LEFT PELVIC LYMPH NODES - A tan-yellow segment of fat (7.0 x 5.2 x 2.0 cm) with eleven possible lymph nodes identified ranging from 0.3 to 2.2 cm in greatest dimension. All nodal tissue is submitted.
SECTION CODE: E1, five possible lymph nodes; E2, three possible lymph nodes; E3, two possible lymph nodes; E4, one possible lymph node.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

T-92000, M-Y1973; T-C4600, M-00110

[page 2 of 4]
[REDACTED]

Specimen Date/Time:

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 3 of 4]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(C) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3). (SEE COMMENT).

TUMOR EXTENDING FOCALLY INTO EXTRAPROSTATIC TISSUE.

FOCAL EXTENSION OF TUMOR TO THE ANTERIOR APICAL MARGIN OF RESECTION CANNOT BE UNEQUIVOCALLY EXCLUDED.

FINAL ANTERIOR APICAL MARGIN FREE OF TUMOR (SEE PART B IN ORIGINAL REPORT).

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH-GRADE.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

COMMENT

The prostate glands three separate foci of prostatic adenocarcinoma, one in the transition zone and two in the peripheral zone. The dominant tumor focus is located in the right and left transition zone with extension into the left peripheral zone. This tumor focus measures 2.5 x 1.5 cm in the largest cross-sectional dimension and it is present in the four cross sections of the prostate, extensively in the apex and focally in the base region. This tumor focus exhibits extraprostatic extension in the anterior apical region and right anterior prostatic surface. Extraprostatic extension is present in two sections and the added length of extraprostatic tumor is less than 2.0 mm. In the anterior apical region, focal extension of tumor the tumor inked margin cannot be excluded. It should be noted that the final margin of resection is represented by the separately submitted specimen B and it is free of tumor. The second tumor focus is located in the left posterior peripheral zone. This tumor focus measures 0.4 x 0.2 cm in the largest cross-sectional dimension and it is present in one cross section and focally in the apical region. The third tumor focus is located in the right posterolateral peripheral zone. This tumor focus measures 0.2 x 0.1 cm in the largest cross-sectional dimension and it is present in one cross section. The nondominant tumor foci are of lower histologic grade and are confined to the prostate with negative margins.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES - A prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia. The prostate gland (4.0 x 3.5 x 4.5 cm, 40 gm, postfixation) has the usual shape. The soft tissue present along the left posterolateral aspect of the prostate appears more abundant than along the right side. A palpable and visible nodule is present on the left anterior surface of the prostate. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the anterior region of the prostate, involving three of the four cross sections (cross sections 1-3).

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: C1, C2, base of right seminal vesicle and right vas deferens; C3, C4, base of left seminal vesicle and

[page 4 of 4]
Specimen Date/Time:

left vas deferens; C5, prostatic base right border; C6-C8, prostatic base right posterior border; C9-C12, prostatic base central portion; C13, prostatic base left border; C14, prostatic base left posterior border; C15, C16, apex anterior; C17-C19, apex left; C20, C21, apex posterior; C22, apex right; C23, detached portions of margin of resection according to specimen radiograph; C24-C39, sections of the four cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (C15 and C16) and orange ink (C34, 35, 38 and 39) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

T-92000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria:	10/23/13	Yes	No
Dual/Synchronous Primary Not at			✓
Case is (check):	QUALIFIED		

Source: NCI Genomic Data Commons file ebbb28e3-64ae-4d5a-8ef4-0eb2080469dc (TCGA-KK-A8IF.BF56F683-5D52-4154-B9D4-1B6D2608C5AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).